Gene-level copy-number profile of tumor specimen TCGA-S9-A89V-01A from TCGA case TCGA-S9-A89V, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 70.0 years (25,570 days).
Specimen TCGA-S9-A89V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.bede2ec1-e22d-42cd-94c7-94f2a8451258.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-S9-A89V-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/548f2da4-6ca0-4e5d-a0a1-ead874263c24

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 254; copy number 1: 10,131; copy number 2: 48,128; copy number 3: 1,307.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-S9-A89V-01A-11D-A36N-01): tumor purity 0.34, ploidy 3.67, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 254 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:23,346,306–26,806,467, 104 genes (broad region; genes not listed).
- chr14:26,775,495–26,918,594, 4 genes (within-gene range 0–1): LINC02294, LINC02293, AL132718.1, MIR4307HG.
- chr20:18,220,113–24,318,086, 146 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 7,710. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
